Gene-level copy-number profile of tumor specimen C3L-02345-02 from CPTAC case C3L-02345, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 61.8 years (22,572 days).
Specimen C3L-02345-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file afd22ebd-4a02-42fc-b1fd-ef173d595d54.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02345-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/834b6205-c3ab-434e-816e-c4332f373cfc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 13,111; copy number 2: 41,452; copy number 3: 3,650; copy number 5: 63; copy number 6: 124.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 187 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:122,399,551–123,072,925, 16 genes, copy number 5: HSF2, Z99129.4, SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2, AL512283.1, AL512283.3, RN7SL564P, FABP7, SMPDL3A, ATP5MGP2, AL591428.1, CLVS2.
- chr8:69,424,849–71,815,625, 39 genes, copy number 5: LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2, AC009446.1, AC104012.1, U8.
- chr8:78,268,637–81,284,777, 58 genes, copy number 6: PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5.
- chr8:125,648,327–130,655,712, 66 genes, copy number 6 (broad region; genes not listed).
- chr8:138,130,023–139,704,109, 8 genes, copy number 5: FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9.

Autosomal genes at a single copy (total copy number 1): 13,111. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
